Gene-level copy-number profile of tumor specimen C3L-05302-01 from CPTAC case C3L-05302, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 72.7 years (26,559 days).
Specimen C3L-05302-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8233dffa-ca60-4b9a-adfc-a1625192e10a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05302-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/f7fc5945-caee-4fdc-b0eb-1737129ea4f3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 44; copy number 2: 7,523; copy number 3: 902; copy number 4: 46,077; copy number 5: 546; copy number 6: 3,766; copy number 7: 23; copy number 8: 6; copy number 9: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,200,756–7,200,857, 1 gene: AF228730.1.
- chr8:7,926,337–7,952,413, 2 genes: ZNF705B, DEFB108A.
- chr8:7,967,344–7,973,253, 2 genes (within-gene range 0–4): AC130365.1, USP17L8.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,128,103, 10 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,191,563, 1 gene, copy number 10: RPS3AP33.
- chr8:12,095,176–12,099,536, 1 gene, copy number 9: DEFB108D.

Autosomal genes at a single copy (total copy number 1): 44. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
